Somatic mutation profile of tumor specimen TCGA-HC-8266-01A (aliquot TCGA-HC-8266-01A-11D-2260-08) from TCGA case TCGA-HC-8266, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.5 years (20,280 days).
Specimen TCGA-HC-8266-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 927e3067-c0b0-40c6-b8b7-085d1efb30b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8266-10A (Blood Derived Normal), aliquot TCGA-HC-8266-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65ba46fd-6c34-40ef-adaf-74995e3dc29f

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782111334, COSV59990788; called by muse, mutect2, varscan2
- CCDC191 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779640915, COSV55671910; called by muse, mutect2, varscan2
- CDC14B | c.809C>G p.A270G | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); catalogued as COSV55787648; called by muse, mutect2
- DDX3Y | c.163A>G p.K55E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.103); catalogued as COSV60176864; called by muse, mutect2, varscan2
- GPR158 | c.3491C>T p.P1164L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs924957375, COSV66265376, COSV66269369; called by muse, mutect2
- GRIN2B | c.1034A>T p.E345V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV74205760; called by muse, mutect2
- KRTAP19-6 | c.67T>A p.Y23N | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.272); catalogued as COSV61844027, COSV61844234; called by muse, mutect2
- LHX8 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs776961606, COSV53956297; called by muse, mutect2, varscan2
- NAV2 | c.922C>T p.R308C (on ENST00000396087 / NM_001244963.2; = p.R285C on NM_145117.5) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs200244681, COSV62321832; called by muse, mutect2, varscan2
- NLRP3 | c.2089C>T p.R697* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as rs1191108022, COSV60221776, COSV60222875; called by muse, mutect2, varscan2
- PCDHB2 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV50571098; called by muse, mutect2, varscan2
- PDE3B | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs749703705, COSV56383120; called by muse, mutect2, varscan2
- PICALM | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV62670461; called by muse, mutect2, varscan2
- PTPN3 | c.1043T>G p.M348R | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.661); catalogued as COSV52705400; called by muse, mutect2, varscan2
- RBL2 | c.2176A>G p.T726A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV50876677; called by muse, mutect2, varscan2
- GATAD2B | c.1152C>G p.A384= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV64084006; called by muse, mutect2
- MAP3K11 | c.1092C>T p.H364= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV58419485; called by muse, mutect2, varscan2
- MYO3A | c.3570A>G p.K1190= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56329284; called by muse, mutect2, varscan2
- PLAC8 | c.204C>T p.V68= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs776954047, COSV61047308; called by muse, mutect2
- SLC30A9 | c.1263G>A p.L421= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as COSV52555742; called by muse, mutect2, varscan2
- STKLD1 | c.846C>G p.P282= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV64312523; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1393A>T | RNA (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
